Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3892, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3892-01A (Primary Tumor).

Diagnosis:

This is a moderately differentiated adenocarcinoma of the rectum of histopathological grade G2, with erosions of the inner tumor surface with peritumorous chronic recurrent secondary inflammation, with tumor infiltration of the rectal wall layers extending into the submucosa and, in places, as far as (but not into) the tunica muscularis with tumor-free lymph nodes (0/17) with a moderate chronic lymphadenitis and tumor-free overview slices from all other resection material portions described.

According to the section preparations available, the tumor spread of the rectal carcinoma corresponds to a tumor stage of pT1, pN0 (0/17), MX, R0

Tumor classification:

ICDO-DA M-8140/3.

Source: NCI Genomic Data Commons file 5ed9cabb-1ecd-4dfe-b154-5e5c30581f08 (TCGA-AG-3892.BACEC435-85E6-4B8B-A234-D50CEBFA30A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).